Somatic mutation profile of tumor specimen MP2PRT-PAVXBA-TMP1-A (aliquot MP2PRT-PAVXBA-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVXBA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,137 days).
Specimen MP2PRT-PAVXBA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff567dca-2372-4ae2-a55a-6a5eefc71afc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXBA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXBA-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97470dfb-78b1-486c-810a-21e3f64b65b7

The open-access MAF lists 84 somatic variants for this specimen: 56 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 25, Nonsense Mutation 5, 5'UTR 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOT | c.1825G>T p.A609S (on ENST00000371959 / NM_001113490.1; = p.A200S on NM_133265.3) | Missense Mutation (SNP) | VAF 42/646 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59068723; called by muse, mutect2
- AMOT | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 29/745 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV59062497; called by muse, mutect2
- AP002748.5 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV59148959; called by muse, mutect2, varscan2
- BIN2 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 87/375 reads (23%) | catalogued as rs763415924, COSV57203665; called by muse, mutect2, varscan2
- BRS3 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 46/447 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs1180255853, COSV65711195; called by muse, mutect2, varscan2
- CACNA1H | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 47/716 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs771267832, COSV62001571; called by muse, mutect2
- CHST5 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 72/497 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV60338441; called by muse, mutect2, varscan2
- CUBN | c.2935C>G p.L979V | Missense Mutation (SNP) | VAF 54/401 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs762283464; called by muse, mutect2, varscan2
- FAT1 | c.4900G>C p.D1634H | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV71673453; called by muse, mutect2
- GALNT14 | c.1584G>C p.E528D | Missense Mutation (SNP) | VAF 42/419 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV100205261, COSV61107207; called by muse, mutect2, varscan2
- GCHFR | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1490713312; called by muse, mutect2
- KRT18 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1355185338, COSV66316590; called by muse, mutect2, varscan2
- MYH7B | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 26/447 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1196151062; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- NSMF | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 62/575 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs1038133430, COSV52993979; called by muse, mutect2, varscan2
- OR14C36 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as rs776779347, COSV100507658, COSV58602490; called by muse, mutect2
- PCDHA4 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs1554125129, COSV63546236; called by muse, mutect2, varscan2
- PCDHGA3 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 323/840 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.185); catalogued as rs745349592, COSV53916955, COSV54017901; called by muse, mutect2, varscan2
- PHRF1 | c.2218G>A p.E740K (on ENST00000264555 / NM_001286581.2; = p.E739K on NM_020901.4) | Missense Mutation (SNP) | VAF 58/942 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as rs1404056560; called by muse, mutect2
- PTPRO | c.2805C>G p.D935E (on ENST00000281171 / NM_030667.3; = p.D907E on NM_002848.4) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV55518404; called by muse, varscan2
- RBFOX2 | c.1073G>A p.R358Q (on ENST00000438146 / NM_001349995.2; = p.R284Q on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/461 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1251296335, COSV53268203; called by muse, mutect2, varscan2
- SLC7A6OS | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs201688620; called by muse, mutect2, varscan2
- SYT12 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV67353609; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.025); catalogued as rs1210828526; called by muse, mutect2, varscan2
- ZBTB21 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 48/376 reads (13%) | catalogued as rs759817211; called by muse, mutect2
- ZFPM1 | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 73/906 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs762934163; called by muse, mutect2
- ABCA12 | c.1367C>T p.S456F (on ENST00000272895 / NM_173076.3; = p.S138F on NM_015657.3) | Missense Mutation (SNP) | VAF 53/381 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ABHD16A | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 36/682 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.099); called by muse, mutect2
- ARFGEF2 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AS3MT | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.27); called by muse, mutect2
- CAND1 | c.3145C>T p.L1049F | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CAPN6 | c.465G>C p.M155I | Missense Mutation (SNP) | VAF 87/553 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CAPRIN2 | c.1223C>G p.T408S | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- CHD9 | c.6671G>C p.S2224T | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ENPP4 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- EPPK1 | c.5857G>A p.E1953K | Missense Mutation (SNP) | VAF 248/598 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EXOC2 | c.591G>C p.K197N | Missense Mutation (SNP) | VAF 132/321 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM47E-STBD1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- FDPS | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 100/398 reads (25%) | called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714668 GTTTTCACACTGTGTCTCTCGCACAGT>CCTGGGG | Missense Mutation (DEL) | VAF 13/54 reads (24%) | called by mutect2*, pindel
- IGHV3-43 | chr14:106470258 CTGTGTAT>A | Missense Mutation (DEL) | VAF 86/235 reads (37%) | called by pindel, varscan2*
- LIFR | c.2761G>C p.E921Q | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MYH13 | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 47/556 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- NKX1-2 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 48/928 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PARP14 | c.5279C>G p.S1760* | Nonsense Mutation (SNP) | VAF 38/352 reads (11%) | called by muse, mutect2, varscan2
- PASK | c.133C>G p.H45D | Missense Mutation (SNP) | VAF 32/626 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.058); called by muse, mutect2
- RABGAP1 | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBMXL3 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 64/818 reads (8%) | called by muse, mutect2
- RNF220 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 164/433 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- SCAF1 | c.3493C>G p.L1165V | Missense Mutation (SNP) | VAF 136/551 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SETDB1 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- SLCO6A1 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SRSF5 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 65/685 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZBTB7A | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF565 | c.760C>G p.Q254E (on ENST00000355114; = p.Q214E on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ZSWIM8 | c.3274dup p.S1092Ffs*4 (on ENST00000605216 / NM_001242487.2; = p.S1097Ffs*4 on NM_015037.3) | Frame Shift Ins (INS) | VAF 141/385 reads (37%) | called by mutect2, pindel, varscan2
- AC092143.1 | c.2331C>T p.A777= | Silent (SNP) | VAF 214/529 reads (40%) | catalogued as rs200607346, COSV100205674; called by muse, mutect2, varscan2
- AIFM2 | c.303C>T p.P101= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- BIRC6 | c.4671C>G p.L1557= | Silent (SNP) | VAF 32/495 reads (6%) | called by muse, mutect2
- CRACD | c.2700C>T p.L900= | Silent (SNP) | VAF 289/692 reads (42%) | catalogued as COSV99950049; called by muse, mutect2, varscan2
- DHDH | c.690C>T p.I230= | Silent (SNP) | VAF 53/400 reads (13%) | called by muse, mutect2, varscan2
- DNAH9 | c.8805G>A p.E2935= | Silent (SNP) | VAF 23/419 reads (5%) | catalogued as rs903855924, COSV52350707; called by muse, mutect2
- FBLN1 | c.1335C>T p.C445= | Silent (SNP) | VAF 104/316 reads (33%) | called by muse, mutect2, varscan2
- GRXCR1 | c.291C>T p.V97= | Silent (SNP) | VAF 25/509 reads (5%) | called by muse, mutect2
- KLHL32 | c.96G>A p.L32= | Silent (SNP) | VAF 24/442 reads (5%) | catalogued as rs1384381897, COSV100987296; called by muse, mutect2
- MAGI2 | c.3639C>T p.L1213= | Silent (SNP) | VAF 30/620 reads (5%) | catalogued as COSV62634902; called by muse, mutect2
- MPHOSPH9 | c.153G>A p.K51= | Silent (SNP) | VAF 26/379 reads (7%) | called by muse, mutect2
- MTMR11 | c.585C>T p.L195= (on ENST00000439741 / NM_001145862.2; = p.L123= on NM_181873.3) | Silent (SNP) | VAF 93/483 reads (19%) | catalogued as rs782294000; called by muse, mutect2, varscan2
- OR1S1 | c.786A>G p.L262= | Silent (SNP) | VAF 161/378 reads (43%) | catalogued as rs764704549; called by muse, mutect2, varscan2
- PACS2 | c.2454G>A p.K818= | Silent (SNP) | VAF 28/431 reads (6%) | called by muse, mutect2
- PLSCR3 | c.147C>T p.F49= | Silent (SNP) | VAF 73/741 reads (10%) | catalogued as COSV61169940, COSV61170757; called by muse, mutect2
- RETREG1 | c.297C>T p.F99= | Silent (SNP) | VAF 31/508 reads (6%) | catalogued as rs1246227310, COSV100104529; called by muse, mutect2
- SLC12A1 | c.786G>A p.L262= | Silent (SNP) | VAF 164/462 reads (35%) | called by muse, mutect2, varscan2
- SLC6A6 | c.1824C>T p.L608= | Silent (SNP) | VAF 81/388 reads (21%) | catalogued as rs1423397444, COSV56119543; called by muse, mutect2, varscan2
- UCP1 | c.309C>T p.L103= | Silent (SNP) | VAF 59/227 reads (26%) | called by muse, mutect2, varscan2
- USP22 | c.756G>A p.A252= | Silent (SNP) | VAF 213/501 reads (43%) | catalogued as rs375910145; called by muse, mutect2, varscan2
- VWCE | c.1062C>T p.L354= | Silent (SNP) | VAF 57/745 reads (8%) | called by muse, mutect2
- WARS1 | c.756G>A p.V252= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as rs1313726047, COSV59925380; called by muse, mutect2, varscan2
- ZFR2 | c.2394C>G p.L798= | Silent (SNP) | VAF 40/623 reads (6%) | catalogued as COSV99508045; called by muse, mutect2
- ZNF565 | c.984C>T p.F328= (on ENST00000355114; = p.F288= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/560 reads (7%) | catalogued as rs146589483; called by muse, mutect2
- ZNF714 | c.375C>G p.V125= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- LINC01278 | n.553C>G | RNA (SNP) | VAF 26/366 reads (7%) | called by muse, mutect2
- MYCN | c.-1G>A | 5'UTR (SNP) | VAF 30/506 reads (6%) | catalogued as COSV99808189; called by muse, mutect2
- NTRK3 | c.1586-40533C>T | Intron (SNP) | VAF 37/292 reads (13%) | catalogued as COSV100448009; called by muse, mutect2, varscan2
